Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A1QM, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A1QM-01A (Primary Tumor).

[page 1 of 3]
Reviewer Initials: EB	Reviewed: 3/11/11	

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year old male with FNA papillary on left thyroid nodule.

Specimens Submitted:

- 1: SP: Right paratracheal lymph node (fs)
- 2: SP: Total thyroidectomy

DIAGNOSIS:

1. SP: Right paratracheal lymph node (fs):

Lymph Node Dissection:

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 0

2. SP: Total thyroidectomy:

Tumor Type:

Papillary microcarcinoma with tall cell features

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Marked stromal reaction

Tumor Size:

Greatest diameter is 0.7 cm.

Tumor Encapsulation:

None identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Separate focus of papillary microcarcinoma (0.25 cm) in right lobe.

Adenoma(s) (away from the carcinoma):

ICD-O-3

Carcinoma, tall cell 8344/3 (Path Report)

Carcinoma, papillary + follicular 8340/3 (CQCF)

Site: thyroid, NOS C73.9 *hw 3/17/11*

[page 2 of 3]
Not Identified
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
of mild degree.
Parathyroid Glands:
Not identified

Lymph Nodes:
One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Right paratracheal lymph node" and consists of a piece of adipose tissue measuring 0.6 x 0.4 x 0.2 cm. on cut section, there is a 0.3 cm lymph node which is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh, labeled "total thyroidectomy, stitch marks left lobe of thyroid" and consists of a thyroid weighing 28 g. The right lobe measures 5.4 x 3.0 x 1.8 cm, the left lobe measures 5.5 x 3.5 x 2.5 cm and the isthmus measures 0.8 x 0.8 x 0.3cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 0.7 x 0.6 x 0.5 cm white firm nodule in the left lobe. No other lesion is seen in the residual left lobe and right lobe. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: SP: Right paratracheal lymph node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	1
10	LL	10
7	RL	7

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 3 of 3]
1. FROZEN SECTION DIAGNOSIS: SP: RIGHT PARATRACHEAL LYMPH NODE (FS): BENIGN LYMPH NODE. ,
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file dd2cffea-73f6-4347-994f-f2c485609876 (TCGA-DJ-A1QM.0CE9565E-A607-433F-AA64-5424F970836F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).